Somatic mutation profile of tumor specimen TCGA-DJ-A2PT-01A (aliquot TCGA-DJ-A2PT-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2PT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 70.7 years (25,837 days).
Specimen TCGA-DJ-A2PT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31f9d70d-86e1-4c8d-8553-23b723854327.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PT-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PT-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65da46bc-822b-497b-8823-cdcd0be8caf5

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- B3GAT1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as rs750780574, COSV57000294; called by muse, mutect2, varscan2
- CBFA2T2 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60073102; called by muse, mutect2, varscan2
- GPM6B | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV57424221; called by muse, mutect2
- PRDM8 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.059); catalogued as rs767271678, COSV60204799; called by muse, mutect2, varscan2
- TBC1D7 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV58244934; called by muse, mutect2, varscan2
- TRMT6 | c.888G>A p.Q296= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV52545023; called by muse, mutect2, varscan2
